Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A7IK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A7IK-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Form Revised

Fax:

Clinical Case Report (For Collection of Cancerous Tissue)

ICD O-3

Carcinoma, hepatocellular
NDS 817813

Site Liver C22.0

W 10/10/13

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight		Blood Pressure	Heart Rate
☒ Male ☐ Female			12/7	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain; tired & eating
Symptoms: yellow skin; weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1/2 p/day	35 (yrs)	3 months ago (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1 drink/day	(yrs)	6 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☒ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT	A tumour was found in the liver	
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes		Location of Suspected Distant Metastasis
Clinical Staging		Date of Diagnosis
T ₃ N ₀ M ₀ Stage: IIIA		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Resection of the right liver.		
Primary Tumor		
Organ	Detailed Location	Size
Liver tumor.	RIGHT LIVER	10 x 8 x 7 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T ₃ N ₀ M ₀		Stage: TTT 1

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____
Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
min		min		min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	10 x 8 x 7 cm	Right Liver	5 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃ N ₀ M ₀ Stage: IIIA			
Notes:			

[page 5 of 5]
IRB APPROVED

Form Revised

Tel:

ax:

Consolidated Pathology Diagnosis

Histological Pattern									
Cell Distribution			Structural Pattern						
	+	-		+	-				
Diffuse		X	Streaming						
Mosaic	X		Storiform						
Necrosis		X	Fibrosis						
Lymphocytic Infiltration	X		Palisading						
Vascular Invasion		X	Cystic Degeneration						
Clusterized		X	Bleeding						
Alveolar Formation		X	Myxoid Change						
Indian File		X	Psammoma/Calcification						

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		

Cellular Differentiation: ☐ Well ☐ Moderate ☒ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis				X
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity				X

Nuclear Grade: ☒ III

D1 80% D2 80% D3 80% D4 80%

Final Pathology Report

Histological Diagnosis: Hepatocellular carcinoma Grade: 2

Adenoid type

Comments:

Date

Source: NCI Genomic Data Commons file ea8b8bd8-29a2-4587-8487-afb6b3c5133c (TCGA-CC-A7IK.6944ABF0-8C64-48D5-920A-6FA6DAC8A57B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).